Somatic mutation profile of tumor specimen TCGA-33-4587-01A (aliquot TCGA-33-4587-01A-11D-2122-08) from TCGA case TCGA-33-4587, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, small cell, nonkeratinizing; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 63.1 years (23,062 days).
Specimen TCGA-33-4587-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b19748df-c405-477d-b801-1dd2bdb609a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-33-4587-11A (Solid Tissue Normal), aliquot TCGA-33-4587-11A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/716aa639-2741-4c78-9232-938babac66f4

The open-access MAF lists 241 somatic variants for this specimen: 178 protein-altering or splice-affecting, 55 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 144, Silent 55, Nonsense Mutation 13, Frame Shift Del 7, Splice Site 6, Splice Region 5, RNA 3, Frame Shift Ins 3, Intron 2, 5'UTR 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LAMA2 | c.1467+1G>T p.X489_splice | Splice Site (SNP) | VAF 17/48 reads (35%) | catalogued as rs1554234161, COSV101370410; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.724T>G p.C242G | Missense Mutation (SNP) | VAF 34/44 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519982, CM107067, COSV52660956, COSV52677021, COSV52760397, COSV52839973; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.3145C>G p.P1049A | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.49); catalogued as COSV99272351, COSV99273709; called by muse, mutect2, varscan2
- ADGRE2 | c.2352+1G>C p.X784_splice | Splice Site (SNP) | VAF 59/84 reads (70%) | catalogued as COSV100215958; called by muse, mutect2, varscan2
- AHCTF1 | c.4631C>G p.P1544R (on ENST00000366508; = p.P1518R on NM_015446.5) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100403572; called by muse, mutect2, varscan2
- ALPK1 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99453964; called by muse, mutect2, varscan2
- ALPK1 | c.1096A>G p.R366G | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV99453967; called by muse, mutect2, varscan2
- AMY1C | c.879G>A p.K293= | Splice Region (SNP) | VAF 69/733 reads (9%) | catalogued as COSV64407220; called by muse, mutect2, varscan2
- AOC1 | c.2122del p.L708Wfs*7 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | catalogued as COSV62871244; called by mutect2, pindel, varscan2
- ARNTL2 | c.565-2A>G p.X189_splice | Splice Site (SNP) | VAF 21/37 reads (57%) | catalogued as COSV99667711; called by muse, mutect2, varscan2
- ARSL | c.1545C>A p.D515E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.093); catalogued as COSV101140496; called by muse, mutect2, varscan2
- ATG7 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as rs1176808145, COSV100607208; called by muse, mutect2, varscan2
- ATP6V1A | c.1291G>T p.V431L | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as COSV99850085; called by muse, mutect2, varscan2
- BMP10 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV54894935, COSV99770388; called by muse, varscan2
- BNC1 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.272); catalogued as COSV100597149, COSV61757534; called by muse, mutect2, varscan2
- C1QC | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101009461; called by muse, mutect2, varscan2
- C6 | c.765C>A p.Y255* | Nonsense Mutation (SNP) | VAF 23/85 reads (27%) | catalogued as COSV99666994; called by muse, mutect2, varscan2
- CCDC33 | c.1312G>C p.A438P | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99173263; called by muse, mutect2, varscan2
- CD163 | c.1099+2T>G p.X367_splice | Splice Site (SNP) | VAF 29/75 reads (39%) | catalogued as COSV100775815; called by muse, mutect2, varscan2
- CDK12 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV101420434; called by muse, mutect2, varscan2
- CEP290 | c.1261A>G p.K421E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100468572; called by muse, mutect2, varscan2
- CILP2 | c.3332G>T p.R1111L | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs1204943198; called by muse, mutect2, varscan2
- CLTB | c.516C>T p.Y172= | Splice Region (SNP) | VAF 28/36 reads (78%) | catalogued as rs1275000391, COSV100124965, COSV60043931; called by muse, mutect2, varscan2
- CNOT2 | c.865A>G p.K289E | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as COSV99972584; called by muse, mutect2, varscan2
- CPT1A | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.477); catalogued as COSV55752831; called by muse, mutect2, varscan2
- CRB1 | c.2503C>A p.L835I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100957851; called by muse, mutect2, varscan2
- CSMD1 | c.4989G>T p.V1663= (on ENST00000520002; = p.V1662= on NM_033225.6) | Splice Region (SNP) | VAF 6/12 reads (50%) | catalogued as rs1250837936, COSV100147055; called by muse, varscan2
- CSMD3 | c.1249C>A p.P417T | Missense Mutation (SNP) | VAF 77/106 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99832791; called by muse, mutect2, varscan2
- CTNND2 | c.1384C>A p.P462T | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as COSV100475830; called by muse, mutect2, varscan2
- CUL1 | c.1094T>C p.M365T | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100296612; called by muse, mutect2, varscan2
- CX3CR1 | c.638G>T p.R213I | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT tolerated (0.18); PolyPhen benign (0.335); catalogued as COSV100843187; called by muse, mutect2, varscan2
- DBN1 | c.749G>C p.R250P | Missense Mutation (SNP) | VAF 74/97 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52793161, COSV99445937; called by muse, mutect2, varscan2
- DENND4A | c.4715C>G p.S1572* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV71267075; called by muse, mutect2, varscan2
- DGAT1 | c.1009T>A p.F337I | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs782321541, COSV100184018; called by muse, mutect2, varscan2
- DMD | c.7050G>T p.Q2350H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.785); catalogued as rs761082809, COSV100627047; called by muse, mutect2, varscan2
- DMD | c.3034T>A p.S1012T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100819399; called by muse, mutect2, varscan2
- DNAH8 | c.2182A>T p.K728* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100544821; called by muse, mutect2, varscan2
- EMSY | c.3563C>T p.P1188L | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.245); catalogued as COSV100595659; called by muse, mutect2, varscan2
- EPHA7 | c.200del p.P67Rfs*34 | Frame Shift Del (DEL) | VAF 34/137 reads (25%) | catalogued as COSV65170562; called by mutect2, pindel, varscan2
- EPN3 | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV99276908; called by muse, mutect2
- ERBB2 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV54063501, COSV54069910; called by muse, mutect2, varscan2
- ESF1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs755033086, COSV99176341; called by muse, mutect2, varscan2
- FAM47C | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.687); catalogued as rs1556332293, COSV100792488; called by muse, mutect2, varscan2
- FAM53C | c.584G>T p.S195I | Missense Mutation (SNP) | VAF 108/126 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV99524353; called by muse, mutect2, varscan2
- FAM71C | c.156G>C p.Q52H | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100175736; called by muse, mutect2, varscan2
- FASTK | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV52542266; called by muse, mutect2, varscan2
- FCHO2 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 29/32 reads (91%) | catalogued as COSV99821697; called by muse, mutect2, varscan2
- FER1L6 | c.3073G>T p.G1025C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV101205790; called by muse, varscan2
- FKBP5 | c.1175C>A p.S392Y | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as rs1360651213, COSV100616151; called by muse, mutect2, varscan2
- FLNA | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 122/150 reads (81%) | catalogued as COSV100774656; called by muse, mutect2, varscan2
- FMN2 | c.3278G>A p.G1093E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as COSV100144764, COSV100146978; called by muse, mutect2, varscan2
- FUCA2 | c.538T>C p.Y180H | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99136056; called by muse, mutect2, varscan2
- GALNTL6 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101560259; called by muse, mutect2, varscan2
- GAS2L3 | c.1108C>A p.R370S | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV99902833, COSV99903254; called by muse, mutect2, varscan2
- GP2 | c.1560C>A p.F520L (on ENST00000381362 / NM_001007240.3; = p.F517L on NM_001502.4) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV100221458, COSV56896463; called by muse, mutect2, varscan2
- GPKOW | c.1015C>A p.R339= | Splice Region (SNP) | VAF 17/38 reads (45%) | catalogued as COSV50242543, COSV99332611; called by muse, mutect2, varscan2
- GRM8 | c.1345G>T p.V449L | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV100282603; called by muse, mutect2, varscan2
- HUWE1 | c.2406G>T p.L802F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99471891; called by muse, mutect2, varscan2
- HUWE1 | c.720G>C p.M240I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99470886, COSV99471895; called by muse, mutect2, varscan2
- INHBA | c.1141C>A p.H381N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV54221134, COSV99637576; called by muse, mutect2, varscan2
- INPP5D | c.2961G>T p.R987S (on ENST00000445964 / NM_001017915.3; = p.R986S on NM_005541.5) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.122); catalogued as COSV100856757, COSV64038812; called by muse, mutect2, varscan2
- INPP5K | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as COSV100233721; called by muse, mutect2, varscan2
- ISL2 | c.803A>G p.Q268R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1299245053, COSV99320627; called by muse, mutect2, varscan2
- ITGA4 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99276204; called by muse, mutect2, varscan2
- ITGA8 | c.2868C>A p.H956Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100959153, COSV65229528; called by muse, mutect2, varscan2
- ITIH6 | c.1933G>T p.V645L | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs757787153, COSV99513228; called by muse, mutect2, varscan2
- KCNA5 | c.588del p.F196Lfs*162 | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | catalogued as COSV52907189; called by mutect2, pindel, varscan2
- KCNMB4 | c.578G>T p.C193F | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99253102; called by muse, mutect2, varscan2
- KIAA1549 | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs750426922, COSV99650667; called by muse, mutect2, varscan2
- KLHL10 | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99505175; called by muse, mutect2, varscan2
- KLHL24 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 75/251 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416650091, COSV99664720; called by muse, mutect2, varscan2
- KLHL28 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs753907485, COSV61888716; called by muse, mutect2, varscan2
- KRTAP10-6 | c.865C>A p.Q289K | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100553261; called by muse, mutect2, varscan2
- LRP1B | c.8487C>G p.D2829E | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101256086; called by muse, mutect2, varscan2
- LRP4 | c.4492C>T p.R1498W | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1431817175, COSV66135820, COSV66138108; called by muse, mutect2, varscan2
- LRRC59 | c.503-1G>T p.X168_splice | Splice Site (SNP) | VAF 41/101 reads (41%) | catalogued as COSV99869536; called by muse, mutect2, varscan2
- MAGEB3 | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100854684, COSV64397790; called by muse, mutect2, varscan2
- MANEA | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as rs771974396, COSV100721507; called by muse, mutect2, varscan2
- MAP10 | c.1988del p.R663Kfs*26 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as COSV69364652; called by mutect2, pindel, varscan2
- MARCHF11 | c.803G>T p.S268I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100197824; called by muse, mutect2, varscan2
- MMP16 | c.1590G>T p.M530I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV54194377, COSV99685927; called by mutect2, varscan2
- MNDA | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.04); catalogued as rs1288507859, COSV63742406; called by muse, mutect2
- MPO | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs765429248, COSV56562794; called by muse, mutect2, varscan2
- MRPL49 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99589077; called by muse, mutect2, varscan2
- MUC16 | c.17999C>G p.T6000R | Missense Mutation (SNP) | VAF 93/113 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as COSV101199667; called by muse, mutect2, varscan2
- MUC16 | c.12451C>A p.P4151T | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.242); catalogued as rs181375018, COSV67491975; called by muse, mutect2, varscan2
- MYH15 | c.2768C>T p.S923F | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1474177084, COSV99843095; called by muse, varscan2
- MYH7 | c.4266G>C p.Q1422H | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100806027; called by muse, mutect2, varscan2
- MYO5B | c.2778G>C p.K926N | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99544596; called by muse, mutect2, varscan2
- NANP | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV59160509; called by muse, mutect2, varscan2
- NAV3 | c.2855A>G p.D952G | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.853); catalogued as COSV99890158; called by muse, mutect2
- NCAN | c.3454G>T p.V1152L | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV53049685, COSV99387131; called by muse, mutect2, varscan2
- NEMF | c.2379C>G p.I793M | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV100027604; called by muse, mutect2, varscan2
- NKAIN3 | c.192G>T p.V64= | Splice Region (SNP) | VAF 23/38 reads (61%) | catalogued as COSV100133366, COSV60652196; called by muse, mutect2, varscan2
- NOP2 | c.1388G>A p.C463Y (on ENST00000322166 / NM_001258308.2; = p.C459Y on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100351078; called by mutect2, varscan2
- NOTCH1 | c.6181-1G>T p.X2061_splice | Splice Site (SNP) | VAF 9/13 reads (69%) | catalogued as COSV53028541, COSV99487534; called by muse, mutect2, varscan2
- NR0B1 | c.1103G>T p.C368F | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.45); PolyPhen probably damaging (1); catalogued as CM105937, COSV100973513; called by muse, mutect2, varscan2
- OPRL1 | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100402062; called by muse, mutect2, varscan2
- OR1F1 | c.68A>G p.Q23R | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as COSV100484413; called by muse, mutect2, varscan2
- OR2G3 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1415224307, COSV100180586; called by muse, mutect2, varscan2
- OR2W3 | c.496T>A p.L166I | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100831669; called by muse, mutect2, varscan2
- OR4C15 | c.707C>T p.P236L (on ENST00000314644; = p.P182L on NM_001001920.2) | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs375979136, COSV58950833; called by muse, mutect2, varscan2
- OR4C46 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs772081877, COSV100060443, COSV100060659; called by muse, mutect2, varscan2
- OR5L2 | c.737C>G p.T246R | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV101004304, COSV65723799; called by muse, mutect2, varscan2
- OR8H2 | c.398C>G p.T133R | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV100542285, COSV57946857; called by muse, mutect2, varscan2
- ORC2 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV52237879, COSV52240743; called by muse, mutect2, varscan2
- PACS1 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as rs1398686303, COSV100269966; called by muse, mutect2, varscan2
- PACS2 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs1424206780, COSV100330720; called by muse, mutect2, varscan2
- PALB2 | c.1972G>T p.E658* | Nonsense Mutation (SNP) | VAF 68/183 reads (37%) | catalogued as CM1410393, COSV55167770; called by muse, mutect2, varscan2
- PCDH17 | c.2188T>A p.C730S | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.222); catalogued as COSV100931597; called by muse, mutect2, varscan2
- PCDHB13 | c.1657G>C p.D553H | Missense Mutation (SNP) | VAF 32/37 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99507178; called by muse, mutect2, varscan2
- PCLO | c.4763G>C p.S1588T | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV100431701; called by muse, mutect2, varscan2
- PDE3A | c.1472G>C p.R491T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV100762069, COSV100762744; called by muse, mutect2, varscan2
- PDILT | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as COSV100199345; called by muse, mutect2, varscan2
- PEG3 | c.1660C>T p.Q554* | Nonsense Mutation (SNP) | VAF 18/107 reads (17%) | catalogued as rs1568639031, COSV55625792; called by muse, mutect2, varscan2
- PEX5L | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99828527; called by muse, mutect2, varscan2
- PKP3 | c.2250C>A p.F750L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV100229989; called by muse, mutect2, varscan2
- PLA2G4D | c.860G>T p.C287F | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV99299633; called by muse, varscan2
- PLCH1 | c.2282del p.P761Lfs*12 (on ENST00000340059 / NM_001130960.2; = p.P773Lfs*12 on NM_014996.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/112 reads (28%) | catalogued as COSV100398621; called by mutect2, pindel, varscan2
- PLIN5 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs199650988, COSV101113493; called by muse, mutect2, varscan2
- POLA1 | c.3958C>A p.L1320M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV100985342; called by muse, mutect2, varscan2
- PPIP5K2 | c.1051G>C p.A351P | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782788409, COSV100383618, COSV100383777; called by muse, varscan2
- PREX2 | c.2849C>T p.T950I | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.097); catalogued as COSV99906805; called by muse, mutect2, varscan2
- PRPF6 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1428313480, COSV99411914; called by muse, mutect2, varscan2
- PRTG | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs376631722, COSV101221365; called by muse, mutect2, varscan2
- PTK2B | c.2780T>C p.L927P | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.363); catalogued as COSV100593818; called by muse, mutect2, varscan2
- RB1 | c.1279A>T p.K427* | Nonsense Mutation (SNP) | VAF 54/61 reads (89%) | catalogued as COSV99924474; called by muse, mutect2, varscan2
- RIPOR2 | c.1589A>C p.H530P | Missense Mutation (SNP) | VAF 59/93 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99429051; called by muse, mutect2, varscan2
- RXRB | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | catalogued as COSV100553897; called by muse, mutect2, varscan2
- SAMD9 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV101180216, COSV101180338; called by muse, mutect2, varscan2
- SASH1 | c.302G>T p.S101I | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV100821164; called by muse, mutect2, varscan2
- SH2D1A | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 51/56 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100758299, COSV63578848; called by muse, mutect2, varscan2
- SH3PXD2B | c.2645A>G p.N882S | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs769448762, COSV61128157; called by muse, mutect2, varscan2
- SHPK | c.1095C>G p.H365Q | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99843842; called by muse, mutect2, varscan2
- SHROOM4 | c.2098A>T p.T700S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV99173382; called by muse, mutect2, varscan2
- SIPA1L1 | c.2811G>T p.E937D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100665477, COSV100666153; called by muse, mutect2
- SLAIN2 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs866212190, COSV99971622; called by muse, mutect2, varscan2
- SLC12A8 | c.1748G>C p.R583T | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as COSV100102279, COSV58871134; called by muse, mutect2, varscan2
- SLC38A5 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100476475; called by muse, mutect2, varscan2
- SLC39A3 | c.635C>G p.A212G | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99514173; called by muse, mutect2, varscan2
- SLC6A6 | c.1099C>A p.P367T | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100692112; called by muse, mutect2, varscan2
- SLC7A5 | c.1044G>T p.R348S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV99879178; called by muse, mutect2
- SRP68 | c.1767G>T p.L589F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100326082; called by muse, mutect2, varscan2
- SSTR3 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 38/41 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100142639; called by muse, mutect2, varscan2
- SSX3 | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 45/287 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs782591173, COSV100035186; called by muse, mutect2, varscan2
- SYNE1 | c.11978A>T p.Q3993L (on ENST00000367255 / NM_182961.4; = p.Q3922L on NM_033071.3) | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV99562150; called by muse, mutect2, varscan2
- SYNE1 | c.6317G>C p.S2106T (on ENST00000367255 / NM_182961.4; = p.S2113T on NM_033071.3) | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV99562152; called by muse, mutect2, varscan2
- SYNE2 | c.4483C>T p.P1495S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.09); catalogued as rs1404962422, COSV100647491, COSV59947497, COSV59957025; called by muse, mutect2, varscan2
- SYNPO2 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV100205465; called by muse, mutect2, varscan2
- TBCB | c.189C>G p.F63L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs151215211, COSV99387486; called by mutect2, varscan2
- TECPR2 | c.2646G>T p.K882N | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100849953; called by muse, mutect2, varscan2
- TENM1 | c.5252C>T p.P1751L | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV100949842; called by muse, mutect2, varscan2
- TMEM71 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV100785587; called by muse, mutect2, varscan2
- TRIM49 | c.273A>T p.Q91H | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.464); catalogued as COSV100316028; called by muse, mutect2
- TTN | c.25377C>G p.I8459M (on ENST00000591111; = p.I7532M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | PolyPhen benign (0.019); catalogued as COSV100610292, COSV60139125; called by muse, mutect2, varscan2
- UMPS | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as rs1457681879, COSV99228966; called by muse, mutect2, varscan2
- USP24 | c.6983G>T p.R2328L | Missense Mutation (SNP) | VAF 94/501 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV99599569; called by muse, mutect2, varscan2
- VIM | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99813056; called by muse, mutect2, varscan2
- VWC2 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100514168; called by muse, mutect2, varscan2
- XRCC2 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV100831622; called by muse, mutect2, varscan2
- YARS1 | c.1034C>G p.S345* | Nonsense Mutation (SNP) | VAF 21/112 reads (19%) | catalogued as COSV100993377; called by muse, mutect2, varscan2
- YARS1 | c.913C>A p.H305N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100993379; called by muse, mutect2, varscan2
- YTHDF1 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100945559; called by muse, mutect2, varscan2
- ZC3H15 | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 45/86 reads (52%) | catalogued as COSV100552055; called by muse, mutect2, varscan2
- ZNF226 | c.2323A>G p.R775G | Missense Mutation (SNP) | VAF 50/56 reads (89%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV100335115; called by muse, mutect2, varscan2
- ZNF419 | c.1465G>T p.G489W | Missense Mutation (SNP) | VAF 110/128 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV99692105; called by muse, mutect2, varscan2
- ZNF579 | c.934T>G p.Y312D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.343); catalogued as COSV100329255; called by muse, mutect2, varscan2
- ZNF649 | c.759G>C p.E253D | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100030981; called by muse, mutect2, varscan2
- ZNF804A | c.2031G>A p.W677* | Nonsense Mutation (SNP) | VAF 44/91 reads (48%) | catalogued as COSV100167583; called by muse, mutect2, varscan2
- ZSWIM1 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.322); catalogued as COSV99666483; called by muse, mutect2, varscan2
- ACE2 | c.1897dup p.Y633Lfs*2 | Frame Shift Ins (INS) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- CPSF4 | c.167_194del p.P56Qfs*26 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel
- GDF2 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- IGHV3-20 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KIF5B | c.1000dup p.E334Gfs*12 | Frame Shift Ins (INS) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- PFKFB1 | c.1202dup p.A402Gfs*6 | Frame Shift Ins (INS) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- ZNF646 | c.4130del p.G1377Dfs*34 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- ZNHIT2 | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- AC098582.1 | c.2751C>T p.F917= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV99985534; called by muse, mutect2, varscan2
- ADAM32 | c.1542A>G p.P514= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV101165385; called by muse, mutect2, varscan2
- AMDHD2 | c.981G>A p.T327= (on ENST00000293971 / NM_001330449.2; = p.T357= on NM_015944.4) | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as rs775945650, COSV99565793; called by muse, mutect2, varscan2
- AP5Z1 | c.51G>A p.Q17= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100804104; called by muse, mutect2, varscan2
- APOB | c.6990A>C p.V2330= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as COSV99265349; called by muse, mutect2, varscan2
- ARMC5 | c.2205C>T p.L735= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs769272226, COSV99192488; called by muse, mutect2, varscan2
- CCNE1 | c.156G>T p.T52= | Silent (SNP) | VAF 22/26 reads (85%) | catalogued as COSV99388367; called by muse, varscan2
- CLMN | c.2979C>T p.L993= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as rs1391916217, COSV100112343; called by muse, mutect2, varscan2
- CRLF2 | c.16C>T p.L6= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV101053696; called by muse, mutect2
- CWC25 | c.261G>T p.L87= | Silent (SNP) | VAF 47/155 reads (30%) | called by muse, mutect2, varscan2
- CYBB | c.1167G>T p.G389= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as CD106238, COSV101059744; called by muse, mutect2, varscan2
- DCAF12 | c.772C>T p.L258= | Silent (SNP) | VAF 33/203 reads (16%) | catalogued as COSV100778369; called by muse, mutect2, varscan2
- DLGAP1 | c.559C>A p.R187= | Silent (SNP) | VAF 50/104 reads (48%) | catalogued as COSV100227886, COSV100230050; called by muse, mutect2, varscan2
- DPP10 | c.537C>T p.V179= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100059213, COSV100063872, COSV59728581; called by muse, mutect2, varscan2
- FAM120A | c.2142G>A p.V714= | Silent (SNP) | VAF 36/44 reads (82%) | catalogued as COSV99465262; called by muse, mutect2, varscan2
- FGD6 | c.2283G>A p.E761= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV100676542; called by muse, mutect2, varscan2
- GRK4 | c.957C>T p.L319= (on ENST00000398052 / NM_182982.3; = p.L287= on NM_005307.3) | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs749246896, COSV61669192; called by muse, mutect2, varscan2
- GTPBP8 | c.69G>C p.L23= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV55607188, COSV99868334; called by mutect2, varscan2
- GUCY1A2 | c.1242A>G p.P414= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV99974389; called by muse, mutect2, varscan2
- GUCY2C | c.84G>A p.Q28= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99663588; called by muse, mutect2, varscan2
- HNF1B | c.1053C>A p.R351= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- IGF2R | c.684T>C p.C228= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- KCTD12 | c.156G>C p.V52= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100499700; called by muse, varscan2
- LATS1 | c.468C>T p.A156= | Silent (SNP) | VAF 56/137 reads (41%) | catalogued as COSV99485854; called by muse, mutect2, varscan2
- MALT1 | c.1728G>C p.R576= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100618677; called by muse, mutect2, varscan2
- MFSD2A | c.1554C>A p.A518= (on ENST00000372809 / NM_001136493.3; = p.A505= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 62/288 reads (22%) | catalogued as COSV100861681; called by muse, mutect2, varscan2
- MUC5B | c.3801C>A p.T1267= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV101500280; called by muse, mutect2, varscan2
- MYBPC3 | c.3048C>T p.G1016= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs397515998, COSV57025499; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- NAA35 | c.315G>A p.L105= | Silent (SNP) | VAF 45/89 reads (51%) | catalogued as rs1308553985, COSV100863326; called by muse, mutect2, varscan2
- OLIG2 | c.171C>G p.G57= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV100324243; called by muse, mutect2, varscan2
- OR13C4 | c.735G>T p.L245= | Silent (SNP) | VAF 76/87 reads (87%) | catalogued as COSV99470135; called by muse, mutect2, varscan2
- OR8H1 | c.501C>T p.F167= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV100477051; called by muse, mutect2, varscan2
- PDS5A | c.3759A>T p.T1253= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as COSV100337328; called by muse, mutect2, varscan2
- PIF1 | c.1830C>T p.F610= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV99164950; called by muse, mutect2, varscan2
- PITPNM2 | c.1080C>T p.P360= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV54898661; called by muse, mutect2, varscan2
- PIWIL4 | c.1752A>G p.K584= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV100133203; called by muse, mutect2, varscan2
- PLEKHO1 | c.921G>A p.R307= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV50310102, COSV50310604; called by muse, mutect2, varscan2
- POLA1 | c.1350T>A p.S450= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV100985341; called by muse, mutect2, varscan2
- POTEE | c.2367C>A p.T789= | Silent (SNP) | VAF 60/161 reads (37%) | catalogued as rs764339068, COSV100387769; called by muse, mutect2, varscan2
- PRR30 | c.762G>C p.V254= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99574463; called by muse, mutect2, varscan2
- PTEN | c.324T>G p.L108= | Silent (SNP) | VAF 46/74 reads (62%) | catalogued as CD1111090, COSV100910151; called by muse, varscan2
- PTK2B | c.2781C>T p.L927= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs368007448; called by muse, mutect2, varscan2
- QPRT | c.33G>A p.P11= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs1309168278, COSV99568960; called by muse, mutect2, varscan2
- RABL6 | c.678C>T p.F226= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100273271; called by muse, mutect2, varscan2
- RASAL1 | c.1686G>T p.P562= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV99921661; called by muse, mutect2, varscan2
- RRBP1 | c.2553G>A p.Q851= (on ENST00000377813 / NM_001365613.2; = p.Q418= on NM_004587.3) | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV99853914; called by muse, mutect2, varscan2
- SRPX | c.1233C>T p.L411= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs1296976586, COSV100656037; called by muse, mutect2, varscan2
- SSPN | c.399G>C p.L133= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV54381131; called by muse, mutect2, varscan2
- TMOD3 | c.780A>G p.L260= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as COSV100419082; called by muse, mutect2, varscan2
- TPTE | c.558T>C p.N186= (on ENST00000618007 / NM_199261.4; = p.N168= on NM_199259.4) | Silent (SNP) | VAF 53/264 reads (20%) | catalogued as rs777767397; called by muse, mutect2, varscan2
- TTC39B | c.1426T>C p.L476= | Silent (SNP) | VAF 73/223 reads (33%) | catalogued as rs1255227613, COSV99894927; called by muse, mutect2, varscan2
- UBAP2L | c.2625G>T p.P875= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as rs563005276, COSV55173498, COSV99671100; called by muse, mutect2, varscan2
- UROD | c.585C>T p.L195= | Silent (SNP) | VAF 20/191 reads (10%) | catalogued as COSV99870148; called by muse, mutect2, varscan2
- ZBTB4 | c.2214G>C p.L738= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100263225; called by muse, mutect2, varscan2
- ZNF831 | c.195G>T p.T65= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV100925982, COSV64038885; called by muse, mutect2, varscan2
- AL645933.1 | chr6:31463976 C>T | 5'Flank (SNP) | VAF 32/128 reads (25%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*5875G>A | 3'UTR (SNP) | VAF 49/165 reads (30%) | catalogued as COSV99950402; called by muse, mutect2, varscan2
- MAST2 | c.500+35019C>T | Intron (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2, varscan2
- OR2W5 | n.1095C>T | RNA (SNP) | VAF 27/111 reads (24%) | catalogued as rs747146806; called by muse, mutect2, varscan2
- PPT1 | c.-1G>A | 5'UTR (SNP) | VAF 38/138 reads (28%) | catalogued as COSV100858372; called by muse, varscan2
- RBPMS2 | c.88-10852G>A | Intron (SNP) | VAF 14/71 reads (20%) | catalogued as COSV100264796; called by muse, mutect2, varscan2
- RNA5-8SP2 | n.119G>C | RNA (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- SSPOP | n.9856G>A | RNA (SNP) | VAF 39/101 reads (39%) | catalogued as COSV100947318; called by muse, mutect2, varscan2
